Somatic mutation profile of tumor specimen 0DRE0Y from CCDI case PBCFPF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 10.8 years (3,932 days).
Specimen 0DRE0Y: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03d2a7d1-e0d8-484c-97d6-46c2dff38f96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRE0G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/473f4686-6ce6-43e4-a3b9-a5ed4dae837d

The open-access MAF lists 173 somatic variants for this specimen: 117 protein-altering or splice-affecting, 29 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 29, Intron 16, 3'UTR 8, Nonsense Mutation 6, Splice Site 3, Frame Shift Del 2, 5'UTR 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRE2 | c.1250C>A p.A417D | Missense Mutation (SNP) | VAF 72/414 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV59692646; called by muse, mutect2, varscan2
- CD55 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 33/555 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as rs1236401085; called by muse, mutect2
- CNGA2 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 74/418 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.162); catalogued as rs1159611500; called by muse, mutect2, varscan2
- CSMD3 | c.2194G>T p.V732F (on ENST00000297405 / NM_001363185.1; = p.V628F on NM_052900.3) | Missense Mutation (SNP) | VAF 169/837 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs986389003, COSV52196498; called by muse, mutect2, varscan2
- CYP11B1 | c.1479G>A p.M493I | Missense Mutation (SNP) | VAF 59/401 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs749247680; called by muse, mutect2, varscan2
- ERBIN | c.1234del p.E412Kfs*69 | Frame Shift Del (DEL) | VAF 81/387 reads (21%) | catalogued as COSV52319435, COSV99397493; called by mutect2, pindel, varscan2
- FAM214A | c.1640G>A p.C547Y | Missense Mutation (SNP) | VAF 79/498 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1163215150; called by muse, mutect2, varscan2
- GPR52 | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 128/584 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as COSV52296355; called by muse, mutect2, varscan2
- HEATR5B | c.5083G>A p.V1695I | Missense Mutation (SNP) | VAF 229/626 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs1309258357; called by muse, varscan2
- HNRNPR | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 67/272 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV56423267; called by muse, mutect2, varscan2
- IL36RN | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.591); catalogued as rs745787528; called by muse, mutect2, varscan2
- INPP4B | c.2639G>A p.R880K | Missense Mutation (SNP) | VAF 185/447 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53729815; called by muse, mutect2, varscan2
- KRT78 | c.1132C>A p.L378M | Missense Mutation (SNP) | VAF 68/427 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1164016799; called by muse, mutect2, varscan2
- LRRC40 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 20/469 reads (4%) | catalogued as COSV63942533; called by muse, mutect2
- MLLT10 | c.603G>T p.L201= | Splice Region (SNP) | VAF 140/390 reads (36%) | catalogued as COSV100307409; called by muse, mutect2, varscan2
- MUC16 | c.19372G>T p.G6458C | Missense Mutation (SNP) | VAF 189/470 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as rs768239699, COSV104431806; called by muse, mutect2, varscan2
- MYOF | c.931G>T p.G311C | Missense Mutation (SNP) | VAF 108/279 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1015714229; called by muse, mutect2, varscan2
- NLGN1 | c.1928C>G p.S643C | Missense Mutation (SNP) | VAF 66/566 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.579); catalogued as COSV64342194; called by muse, mutect2
- OR6Y1 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 120/716 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.122); catalogued as COSV56930279; called by muse, mutect2, varscan2
- PALM3 | c.187G>A p.E63K (on ENST00000340790; = p.E78K on NM_001145028.2) | Missense Mutation (SNP) | VAF 189/488 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as rs1257232803; called by muse, mutect2, varscan2
- PGLYRP4 | c.77C>A p.A26D | Missense Mutation (SNP) | VAF 17/518 reads (3%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.022); catalogued as rs1208028621; called by muse, mutect2
- PIEZO1 | c.2529C>A p.F843L | Missense Mutation (SNP) | VAF 361/898 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.047); catalogued as COSV56333779; called by muse, mutect2, varscan2
- PLA2G12A | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 152/414 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1179245654; called by muse, mutect2
- PLPPR1 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 74/459 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs147722670, COSV66449391; called by muse, mutect2, varscan2
- PRAMEF11 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1011769087; called by muse, mutect2, varscan2
- PSMG2 | c.640A>C p.I214L | Missense Mutation (SNP) | VAF 196/492 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs779332918; called by muse, mutect2, varscan2
- RGPD4 | c.2386-1G>A p.X796_splice | Splice Site (SNP) | VAF 96/675 reads (14%) | catalogued as rs1475296950, COSV100736211; called by muse, mutect2, varscan2
- RUNX1 | c.23G>A p.S8N (on ENST00000344691 / NM_001001890.3; = p.S35N on NM_001754.5) | Missense Mutation (SNP) | VAF 184/459 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1569084822; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SBSN | c.1626C>A p.N542K (on ENST00000452271 / NM_001166034.2; = p.N199K on NM_198538.4) | Missense Mutation (SNP) | VAF 62/356 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as rs745475473, COSV101510033; called by muse, mutect2, varscan2
- SLC22A2 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 104/496 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV65265925; called by muse, mutect2, varscan2
- SLC4A10 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 65/321 reads (20%) | catalogued as rs899870875; called by muse, mutect2, varscan2
- SLIT2 | c.2039G>T p.R680I | Missense Mutation (SNP) | VAF 220/567 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99879563; called by muse, mutect2, varscan2
- SLIT2 | c.4532C>A p.S1511Y | Missense Mutation (SNP) | VAF 127/620 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1182658447, COSV56589915; called by muse, mutect2, varscan2
- UNC13A | c.2515G>C p.V839L | Missense Mutation (SNP) | VAF 34/526 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV53199603; called by muse, mutect2
- USP9X | c.5772G>T p.E1924D | Missense Mutation (SNP) | VAF 209/274 reads (76%) | SIFT tolerated (0.6); PolyPhen benign (0.045); catalogued as COSV61068729; called by muse, mutect2, varscan2
- VHL | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 181/244 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CD093920, CM961430, COSV56545604, COSV56548401; called by muse, mutect2, varscan2
- ZNF334 | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 88/477 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61620715; called by muse, mutect2, varscan2
- ZNF438 | c.1531G>T p.V511F | Missense Mutation (SNP) | VAF 148/712 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs148964717; called by muse, mutect2, varscan2
- ZNF491 | c.292A>C p.T98P | Missense Mutation (SNP) | VAF 129/667 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs369000509, COSV60057089; called by mutect2, varscan2
- ZYG11A | c.1542+1G>T p.X514_splice | Splice Site (SNP) | VAF 114/434 reads (26%) | catalogued as rs1165631326; called by muse, mutect2, varscan2
- ACP3 | c.434C>A p.T145K | Missense Mutation (SNP) | VAF 176/265 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS5 | c.2608G>T p.V870L | Missense Mutation (SNP) | VAF 26/797 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2
- ADCY5 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 137/198 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ADGRE1 | c.890T>C p.I297T | Missense Mutation (SNP) | VAF 117/537 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ADRB1 | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 89/577 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- AHCTF1 | c.670G>T p.V224F (on ENST00000366508; = p.V198F on NM_015446.5) | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ANHX | c.806C>A p.A269E | Missense Mutation (SNP) | VAF 160/437 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD31 | c.3069G>T p.K1023N | Missense Mutation (SNP) | VAF 148/646 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by mutect2, varscan2
- ARHGAP42 | c.2581G>A p.G861S | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C10orf71 | c.3856T>A p.F1286I | Missense Mutation (SNP) | VAF 186/479 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CA6 | c.557A>G p.N186S | Missense Mutation (SNP) | VAF 72/335 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCSER1 | c.2590G>T p.G864* | Nonsense Mutation (SNP) | VAF 111/515 reads (22%) | called by muse, mutect2, varscan2
- CNTN2 | c.385T>G p.F129V | Missense Mutation (SNP) | VAF 108/458 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- COL14A1 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.319); called by muse, mutect2
- CSMD1 | c.794G>T p.S265I | Missense Mutation (SNP) | VAF 143/650 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CYP2B6 | c.300A>T p.K100N | Missense Mutation (SNP) | VAF 41/625 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.542); called by muse, mutect2
- DACT2 | c.2207G>T p.S736I | Missense Mutation (SNP) | VAF 185/467 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- DDX60 | c.100G>T p.V34F | Missense Mutation (SNP) | VAF 58/456 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- DSP | c.5461G>A p.V1821I | Missense Mutation (SNP) | VAF 98/602 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DTHD1 | c.98C>G p.T33R (on ENST00000456874; = p.T158R on NM_001170700.3) | Missense Mutation (SNP) | VAF 93/495 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM217A | c.908A>G p.K303R | Missense Mutation (SNP) | VAF 117/821 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FBXL18 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 107/617 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- FGFBP2 | c.240G>T p.M80I | Missense Mutation (SNP) | VAF 100/602 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GBP5 | c.1382A>C p.K461T | Missense Mutation (SNP) | VAF 86/416 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.05); called by muse, varscan2
- GCN1 | c.19-1G>A p.X7_splice | Splice Site (SNP) | VAF 72/376 reads (19%) | called by muse, mutect2, varscan2
- GIP | c.167C>A p.T56N | Missense Mutation (SNP) | VAF 194/369 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HELB | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 137/773 reads (18%) | called by muse, mutect2, varscan2
- HTR2A | c.209A>T p.H70L | Missense Mutation (SNP) | VAF 25/684 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2
- IGF2BP3 | c.1720C>A p.P574T | Missense Mutation (SNP) | VAF 75/621 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ITGA2B | c.2408G>T p.S803I | Missense Mutation (SNP) | VAF 28/586 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.043); called by muse, mutect2
- ITGA3 | c.3059A>T p.K1020M | Missense Mutation (SNP) | VAF 138/570 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- KIAA0586 | c.2848A>G p.S950G (on ENST00000619416 / NM_001244190.2; = p.S889G on NM_014749.5) | Missense Mutation (SNP) | VAF 64/383 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KIAA1755 | c.3097C>A p.L1033I | Missense Mutation (SNP) | VAF 171/459 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- KIF13B | c.2187G>T p.K729N | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- KIF20B | c.4633A>T p.N1545Y (on ENST00000371728 / NM_001284259.2; = p.N1505Y on NM_016195.4) | Missense Mutation (SNP) | VAF 150/406 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT28 | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 128/539 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- LCE5A | c.343G>T p.G115* | Nonsense Mutation (SNP) | VAF 104/382 reads (27%) | called by muse, mutect2, varscan2
- MAPKBP1 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 85/553 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MDGA2 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.06); called by muse, mutect2
- MMP3 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MUC16 | c.7591C>G p.L2531V | Missense Mutation (SNP) | VAF 140/352 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- MUC5B | c.6128C>A p.P2043Q | Missense Mutation (SNP) | VAF 353/523 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- MYLK | c.545G>T p.C182F | Missense Mutation (SNP) | VAF 11/307 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NAV2 | c.1463G>T p.G488V (on ENST00000396087 / NM_001244963.2; = p.G465V on NM_145117.5) | Missense Mutation (SNP) | VAF 30/508 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); called by muse, mutect2
- NPHP1 | c.200G>T p.S67I | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- NPHS1 | c.3709A>T p.R1237W | Missense Mutation (SNP) | VAF 30/650 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NPY1R | c.780A>C p.R260S | Missense Mutation (SNP) | VAF 97/677 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NSD3 | c.2175del p.H726Tfs*37 | Frame Shift Del (DEL) | VAF 91/513 reads (18%) | called by mutect2, pindel, varscan2
- NTM | c.324T>A p.Y108* | Nonsense Mutation (SNP) | VAF 41/352 reads (12%) | called by muse, mutect2, varscan2
- OR4F17 | c.240C>G p.S80R | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- OR4K1 | c.743T>A p.I248N | Missense Mutation (SNP) | VAF 96/462 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- OR6C6 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 255/619 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PAH | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 25/443 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2
- PM20D2 | c.472G>T p.V158F | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PNISR | c.1922A>T p.K641I | Missense Mutation (SNP) | VAF 83/1068 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); called by muse, mutect2
- POGLUT2 | c.535A>T p.I179F | Missense Mutation (SNP) | VAF 153/456 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- PPIE | c.88G>C p.G30R | Missense Mutation (SNP) | VAF 86/321 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RANBP2 | c.5026G>A p.V1676I | Missense Mutation (SNP) | VAF 132/909 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RHAG | c.800T>C p.L267P | Missense Mutation (SNP) | VAF 242/599 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- RIN3 | c.538T>C p.W180R | Missense Mutation (SNP) | VAF 101/567 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCAF8 | c.3776G>T p.S1259I | Missense Mutation (SNP) | VAF 81/562 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- SLC17A2 | c.281T>C p.I94T | Missense Mutation (SNP) | VAF 99/631 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ST6GAL2 | c.428A>G p.H143R | Missense Mutation (SNP) | VAF 166/772 reads (22%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM42 | c.1997T>A p.L666Q | Missense Mutation (SNP) | VAF 206/312 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TRRAP | c.5518G>T p.V1840L (on ENST00000359863 / NM_001244580.1; = p.V1822L on NM_003496.3) | Missense Mutation (SNP) | VAF 91/679 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TSHB | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TTC9 | c.119C>G p.A40G | Missense Mutation (SNP) | VAF 80/358 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBC | c.1900G>A p.V634I | Missense Mutation (SNP) | VAF 71/388 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); called by muse, varscan2
- UNC13B | c.2768G>T p.C923F | Missense Mutation (SNP) | VAF 186/564 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- USP22 | c.372G>T p.M124I | Missense Mutation (SNP) | VAF 17/511 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- VCAN | c.7403A>G p.H2468R | Missense Mutation (SNP) | VAF 141/641 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VCAN | c.7683T>A p.S2561R | Missense Mutation (SNP) | VAF 126/449 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- VPS13D | c.1140G>T p.Q380H | Missense Mutation (SNP) | VAF 146/586 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- VPS26B | c.535A>C p.N179H | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XRCC4 | c.755G>A p.S252N | Missense Mutation (SNP) | VAF 70/283 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZMYND12 | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 70/409 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- ZNF599 | c.1526G>T p.C509F | Missense Mutation (SNP) | VAF 20/847 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCA4 | c.6199C>T p.L2067= | Silent (SNP) | VAF 66/333 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.2202C>A p.I734= | Silent (SNP) | VAF 25/966 reads (3%) | catalogued as COSV54357005; called by muse, mutect2
- ARHGAP28 | c.777G>A p.P259= (on ENST00000383472 / NM_001366230.1; = p.P100= on NM_001010000.3) | Silent (SNP) | VAF 63/524 reads (12%) | catalogued as rs199607056; called by muse, mutect2, varscan2
- ATG101 | c.90G>A p.L30= | Silent (SNP) | VAF 215/578 reads (37%) | called by muse, mutect2, varscan2
- CACNG7 | c.102G>C p.L34= | Silent (SNP) | VAF 59/417 reads (14%) | called by muse, mutect2, varscan2
- CAPN15 | c.1425G>A p.E475= | Silent (SNP) | VAF 69/359 reads (19%) | called by muse, mutect2, varscan2
- DNAH11 | c.1740G>A p.E580= | Silent (SNP) | VAF 41/311 reads (13%) | called by muse, mutect2, varscan2
- DNAH11 | c.8754A>T p.L2918= | Silent (SNP) | VAF 263/672 reads (39%) | called by muse, mutect2, varscan2
- FBLN1 | c.198G>A p.E66= | Silent (SNP) | VAF 137/617 reads (22%) | catalogued as rs1394015760; called by muse, mutect2, varscan2
- FCN2 | c.48G>T p.L16= | Silent (SNP) | VAF 83/448 reads (19%) | called by muse, mutect2, varscan2
- FCRL5 | c.1566G>T p.V522= | Silent (SNP) | VAF 99/368 reads (27%) | catalogued as COSV62520350; called by muse, mutect2, varscan2
- GSDMD | c.1071G>T p.V357= | Silent (SNP) | VAF 128/547 reads (23%) | called by muse, mutect2, varscan2
- KIAA0930 | c.990G>A p.E330= (on ENST00000336156 / NM_001009880.2; = p.E335= on NM_015264.2) | Silent (SNP) | VAF 116/681 reads (17%) | catalogued as rs762063133; called by muse, mutect2, varscan2
- KIAA1109 | c.7308T>G p.A2436= | Silent (SNP) | VAF 99/586 reads (17%) | called by muse, mutect2, varscan2
- LY9 | c.234C>A p.V78= | Silent (SNP) | VAF 102/447 reads (23%) | called by muse, mutect2, varscan2
- MYCBP2 | c.573G>T p.L191= (on ENST00000357337; = p.L229= on NM_015057.5) | Silent (SNP) | VAF 93/485 reads (19%) | catalogued as COSV62020470; called by muse, mutect2, varscan2
- NLGN1 | c.1983A>G p.Q661= | Silent (SNP) | VAF 141/550 reads (26%) | called by muse, mutect2, varscan2
- NOS2 | c.1752G>C p.R584= | Silent (SNP) | VAF 137/301 reads (46%) | called by muse, mutect2, varscan2
- OR2A4 | c.879C>T p.N293= | Silent (SNP) | VAF 12/864 reads (1%) | called by muse, mutect2
- PLAGL2 | c.942G>T p.L314= | Silent (SNP) | VAF 102/649 reads (16%) | called by muse, mutect2, varscan2
- PNLIP | c.1074G>A p.K358= | Silent (SNP) | VAF 86/492 reads (17%) | called by muse, varscan2
- RCBTB1 | c.762G>C p.L254= | Silent (SNP) | VAF 163/423 reads (39%) | catalogued as rs1238428430; called by muse, mutect2, varscan2
- RNF113B | c.900C>A p.I300= | Silent (SNP) | VAF 165/770 reads (21%) | catalogued as COSV99940366; called by muse, mutect2, varscan2
- SLC6A18 | c.993C>A p.I331= | Silent (SNP) | VAF 122/514 reads (24%) | catalogued as COSV57254841; called by muse, mutect2, varscan2
- TAF1L | c.3843G>C p.L1281= | Silent (SNP) | VAF 130/845 reads (15%) | catalogued as COSV54265286; called by muse, varscan2
- UBR4 | c.10665G>A p.R3555= | Silent (SNP) | VAF 94/402 reads (23%) | catalogued as rs772296545; called by muse, mutect2, varscan2
- WDR1 | c.1230A>G p.P410= (on ENST00000382452; = p.P270= on NM_005112.5) | Silent (SNP) | VAF 82/459 reads (18%) | catalogued as rs747946786; called by muse, mutect2, varscan2
- ZNF236 | c.4803G>C p.T1601= | Silent (SNP) | VAF 34/209 reads (16%) | called by muse, mutect2, varscan2
- ZNF254 | c.165T>C p.A55= | Silent (SNP) | VAF 64/188 reads (34%) | called by muse, mutect2, varscan2
- ARHGAP42 | c.*3796A>T | 3'UTR (SNP) | VAF 251/371 reads (68%) | called by muse, mutect2, varscan2
- CLPSL2 | c.84+41G>T | Intron (SNP) | VAF 78/215 reads (36%) | called by muse, mutect2, varscan2
- DPP3 | c.-6G>A | 5'UTR (SNP) | VAF 44/141 reads (31%) | called by muse, mutect2, varscan2
- DSCR4 | n.173C>A | RNA (SNP) | VAF 36/280 reads (13%) | called by muse, varscan2
- EEF1D | c.807+24G>A | Intron (SNP) | VAF 85/390 reads (22%) | called by muse, mutect2, varscan2
- EIPR1 | c.417-99G>T | Intron (SNP) | VAF 12/98 reads (12%) | called by mutect2, varscan2
- ERCC6 | c.1397+7814G>T | Intron (SNP) | VAF 173/463 reads (37%) | catalogued as rs1273650955; called by muse, mutect2, varscan2
- FAM98C | c.*51A>G | 3'UTR (SNP) | VAF 23/127 reads (18%) | catalogued as rs1266999885; called by muse, mutect2, varscan2
- FANCF | c.*46del | 3'UTR (DEL) | VAF 40/146 reads (27%) | called by mutect2, pindel, varscan2
- FNTA | c.201-46T>G | Intron (SNP) | VAF 50/118 reads (42%) | called by muse, mutect2
- GGH | c.276-68T>C | Intron (SNP) | VAF 33/158 reads (21%) | called by muse, mutect2, varscan2
- HHIPL2 | c.*89G>A | 3'UTR (SNP) | VAF 36/108 reads (33%) | catalogued as rs1418658751; called by muse, mutect2, varscan2
- KLHL29 | c.940+200G>T | Intron (SNP) | VAF 79/546 reads (14%) | called by muse, mutect2, varscan2
- LGALSL | c.*55G>T | 3'UTR (SNP) | VAF 127/303 reads (42%) | called by muse, mutect2, varscan2
- MED25 | c.180+88G>T | Intron (SNP) | VAF 28/169 reads (17%) | called by muse, mutect2, varscan2
- MTA2 | c.882+18G>T | Intron (SNP) | VAF 65/238 reads (27%) | called by muse, mutect2, varscan2
- OR10H1 | c.-41del | 5'UTR (DEL) | VAF 76/224 reads (34%) | called by mutect2, pindel, varscan2
- PHYH | c.246-55G>T | Intron (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- POLR2K | c.154+17G>A | Intron (SNP) | VAF 34/215 reads (16%) | called by muse, mutect2, varscan2
- PRDM2 | c.5036+3774A>T | Intron (SNP) | VAF 141/469 reads (30%) | called by muse, mutect2, varscan2
- RBCK1 | c.167+516A>T | Intron (SNP) | VAF 152/739 reads (21%) | called by muse, mutect2, varscan2
- RHOBTB2 | c.1501+11G>T | Intron (SNP) | VAF 85/378 reads (22%) | called by muse, mutect2, varscan2
- SRP9 | c.*63G>A | 3'UTR (SNP) | VAF 32/132 reads (24%) | called by muse, mutect2, varscan2
- TTC39C | c.1078+9G>T | Intron (SNP) | VAF 104/294 reads (35%) | called by muse, mutect2, varscan2
- UGT8 | c.*49T>A | 3'UTR (SNP) | VAF 85/190 reads (45%) | called by muse, mutect2, varscan2
- ZBED1 | c.*46G>T | 3'UTR (SNP) | VAF 141/276 reads (51%) | called by muse, mutect2, varscan2
- ZFR | c.2836-76G>A | Intron (SNP) | VAF 78/132 reads (59%) | called by muse, mutect2, varscan2
